Somatic mutation profile of tumor specimen C3N-02300-02 (aliquot CPT0126810006) from CPTAC case C3N-02300, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 69.4 years (25,366 days).
Specimen C3N-02300-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69742103-6593-44f9-aaaf-eb28a5b759da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02300-31 (Blood Derived Normal), aliquot CPT0126870002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acce4569-0ec5-4988-9b95-1a93d56a5878

The open-access MAF lists 854 somatic variants for this specimen: 599 protein-altering or splice-affecting, 164 silent, 91 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 492, Silent 164, Intron 42, Nonsense Mutation 34, Frame Shift Del 28, RNA 20, Splice Site 19, Frame Shift Ins 14, 3'UTR 12, 5'UTR 9, Splice Region 8, 5'Flank 6.

Variants (750 of 854; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1B1 | c.1155dup p.I386Hfs*56 | Frame Shift Ins (INS) | VAF 74/408 reads (18%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, varscan2
- FAH | c.615del p.F205Lfs*2 | Frame Shift Del (DEL) | VAF 42/278 reads (15%) | catalogued as rs1057517084; ClinVar: likely pathogenic; called by mutect2, varscan2
- MLH1 | c.2093C>G p.S698* | Nonsense Mutation (SNP) | VAF 63/257 reads (25%) | catalogued as rs587778975, CM942064, COSV51623012, COSV99212376; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 23/120 reads (19%) | catalogued as rs121909227, CM981672, COSV64290622; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SUFU | c.71dup p.A25Gfs*23 | Frame Shift Ins (INS) | VAF 32/146 reads (22%) | catalogued as rs587776579; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.614A>T p.Y205F | Missense Mutation (SNP) | VAF 73/299 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.2542G>C p.G848R | Missense Mutation (SNP) | VAF 44/317 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66064036; called by muse, mutect2, varscan2
- ADAR | c.2908G>A p.A970T | Missense Mutation (SNP) | VAF 19/295 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781413531, COSV52720076; called by muse, mutect2
- ADAR | c.1648G>T p.E550* | Nonsense Mutation (SNP) | VAF 26/200 reads (13%) | catalogued as COSV52715190; called by muse, mutect2, varscan2
- ADGRD1 | c.1286A>G p.H429R | Missense Mutation (SNP) | VAF 16/411 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as rs1255199023; called by muse, mutect2
- AIM2 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.037); catalogued as COSV63701599; called by muse, varscan2
- ARHGEF33 | c.1015G>A p.V339I | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT tolerated (1); PolyPhen possibly damaging (0.729); catalogued as rs762057719; called by muse, mutect2, varscan2
- ATG7 | c.1879C>G p.R627G | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61612024, COSV61615022; called by muse, mutect2, varscan2
- ATP2B2 | c.3073G>A p.V1025M (on ENST00000352432; = p.V991M on NM_001683.5) | Missense Mutation (SNP) | VAF 34/344 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs1472307150; called by muse, mutect2, varscan2
- ATP6AP1 | c.1219G>A p.V407I | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.568); catalogued as rs782410042; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1726C>T p.H576Y | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.105); catalogued as rs752876687; called by muse, mutect2, varscan2
- AVEN | c.798G>T p.R266S | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV60736756; called by muse, mutect2, varscan2
- BCO2 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs200053646, COSV63063817; called by muse, mutect2, varscan2
- BICD2 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs943974428; called by muse, mutect2, varscan2
- BICRA | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as rs144451378; called by muse, mutect2, varscan2
- BRAT1 | c.1880C>T p.A627V | Missense Mutation (SNP) | VAF 52/438 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767664883; called by muse, mutect2, varscan2
- C2CD4C | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 25/358 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs913368732; called by muse, mutect2
- C8A | c.1109G>A p.R370K | Missense Mutation (SNP) | VAF 38/286 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1382747473; called by muse, mutect2, varscan2
- CACNA1H | c.4444C>T p.R1482* | Nonsense Mutation (SNP) | VAF 29/234 reads (12%) | catalogued as rs763390819, COSV61991971; called by muse, mutect2, varscan2
- CACNB2 | c.1735G>A p.V579M (on ENST00000324631 / NM_201596.3; = p.V524M on NM_000724.4) | Missense Mutation (SNP) | VAF 38/376 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.326); catalogued as rs544535665, COSV99995791; called by muse, mutect2, varscan2
- CAMSAP2 | c.2630G>A p.S877N (on ENST00000236925 / NM_001297707.2; = p.S866N on NM_203459.3) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.276); catalogued as rs754283904; called by muse, mutect2, varscan2
- CAPN2 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 22/229 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1436682876, COSV99688873; called by muse, mutect2
- CAPZB | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 41/325 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs1404652678; called by muse, mutect2, varscan2
- CBLN2 | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54051343; called by muse, mutect2, varscan2
- CCDC38 | c.772+1G>T p.X258_splice | Splice Site (SNP) | VAF 10/47 reads (21%) | catalogued as rs779716729; called by muse, mutect2
- CD22 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 52/286 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.131); catalogued as rs1012790288; called by muse, mutect2, varscan2
- CDKL4 | c.406A>T p.K136* | Nonsense Mutation (SNP) | VAF 21/99 reads (21%) | catalogued as COSV66508961; called by muse, mutect2, varscan2
- CEP68 | c.336_338del p.L114del | In Frame Del (DEL) | VAF 27/114 reads (24%) | catalogued as rs749851511; called by mutect2, pindel, varscan2
- CEP85L | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs763347665; called by muse, mutect2, varscan2
- CFAP57 | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100993994, COSV65264736; called by muse, mutect2, varscan2
- CHRNA10 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as rs765435824; called by muse, mutect2, varscan2
- CNTNAP3 | c.3668dup p.A1224Rfs*9 | Frame Shift Ins (INS) | VAF 17/155 reads (11%) | catalogued as rs1316209651; called by mutect2, pindel, varscan2
- COL11A2 | c.3485G>A p.G1162D (on ENST00000341947 / NM_080680.3; = p.G1055D on NM_080679.2) | Missense Mutation (SNP) | VAF 64/558 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1455275715; called by muse, mutect2, varscan2
- COL5A3 | c.1367G>A p.G456D | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1434300582; called by muse, mutect2, varscan2
- COL6A6 | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.196); catalogued as COSV100650252; called by muse, mutect2
- COLEC11 | c.589G>T p.G197C | Missense Mutation (SNP) | VAF 94/451 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104377152; called by muse, mutect2, varscan2
- CORO2B | c.1124C>T p.T375M | Missense Mutation (SNP) | VAF 25/266 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as rs1374708795; called by muse, mutect2
- CRACD | c.1964del p.R655Pfs*22 | Frame Shift Del (DEL) | VAF 50/268 reads (19%) | catalogued as COSV51715473; called by mutect2, varscan2
- CROT | c.102del p.K34Nfs*6 | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | catalogued as rs756999481; called by mutect2, pindel, varscan2
- CYP11A1 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs763099365, COSV51430559; called by muse, mutect2, varscan2
- CYP3A4 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs747540614; called by muse, mutect2, varscan2
- DCAF8L1 | c.1045C>A p.Q349K | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs762197074, COSV101491463; called by muse, mutect2, varscan2
- DDX20 | c.1070A>G p.H357R | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1210789656; called by muse, mutect2, varscan2
- DDX39A | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.251); catalogued as rs141207973; called by muse, mutect2, varscan2
- DGKI | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs1222093392, COSV99933351; called by muse, mutect2, varscan2
- DLL3 | c.1739C>A p.P580H | Missense Mutation (SNP) | VAF 39/366 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV52695959, COSV52696388; called by muse, mutect2, varscan2
- DOCK10 | c.556G>T p.G186C | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776429569, COSV51430080; called by muse, mutect2, varscan2
- DST | c.13118A>T p.Q4373L (on ENST00000361203 / NM_001374722.1; = p.Q1961L on NM_015548.5) | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as rs762832340; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 17/348 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.177); catalogued as rs906643264; called by muse, mutect2
- EIF2AK3 | c.2345G>C p.G782A | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.411); catalogued as COSV57545667; called by muse, mutect2
- EIF4G3 | c.247G>A p.V83I | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated, low confidence (0.38); catalogued as rs1215415339; called by mutect2, varscan2
- EIF4H | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV56082126; called by muse, mutect2, varscan2
- ENG | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 58/318 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.245); catalogued as rs143054595; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ENPP2 | c.2482C>T p.R828C (on ENST00000075322 / NM_001040092.3; = p.R880C on NM_006209.5) | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752514086; called by muse, mutect2, varscan2
- EPB41L1 | c.2144C>T p.A715V | Missense Mutation (SNP) | VAF 37/273 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.039); catalogued as COSV99151502; called by muse, mutect2, varscan2
- EPHB1 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 42/474 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752762812, COSV67674617; called by muse, mutect2
- ERICH3 | c.3626G>A p.R1209H | Missense Mutation (SNP) | VAF 49/334 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1265578555, COSV58600763; called by muse, mutect2, varscan2
- ERO1A | c.164G>A p.R55K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV67470825, COSV67471724; called by muse, mutect2, varscan2
- FAM83A | c.1165C>G p.P389A | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV104372576; called by muse, mutect2, varscan2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 18/100 reads (18%) | catalogued as rs748967872; called by mutect2, varscan2
- FAT4 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.993); catalogued as rs767730943, COSV101272493; called by muse, mutect2, varscan2
- FCHSD1 | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 42/202 reads (21%) | catalogued as rs556350876, COSV53355932; called by muse, mutect2, varscan2
- FLVCR1 | c.371A>G p.Q124R | Missense Mutation (SNP) | VAF 123/709 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1376169334; called by muse, mutect2, varscan2
- FOXR2 | c.905C>A p.P302Q | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99080877; called by muse, mutect2, varscan2
- GNAZ | c.245C>T p.T82I | Missense Mutation (SNP) | VAF 93/495 reads (19%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.961); catalogued as rs761943894; called by muse, mutect2, varscan2
- GOLGA5 | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 9/83 reads (11%) | catalogued as rs780072747; called by muse, mutect2, varscan2
- GRWD1 | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759465666; called by muse, mutect2
- GRXCR1 | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 37/139 reads (27%) | catalogued as COSV67670638; called by muse, mutect2, varscan2
- GSC2 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 59/295 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as rs782761447; called by muse, mutect2, varscan2
- HADHB | c.1110G>A p.M370I | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV58545555; called by muse, mutect2, varscan2
- HBG2 | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 67/390 reads (17%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.884); catalogued as COSV100400592, COSV100400758; called by muse, mutect2, varscan2
- HEATR1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV100857205; called by muse, mutect2, varscan2
- HIF1AN | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as rs1158954260; called by muse, mutect2, varscan2
- HLA-DRA | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 41/300 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs772798906, COSV66622472; called by muse, mutect2, varscan2
- HYAL2 | c.442A>G p.K148E | Missense Mutation (SNP) | VAF 94/342 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99222647; called by muse, mutect2, varscan2
- IMPG1 | c.1582C>A p.P528T | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV100886493, COSV64059379; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 18/122 reads (15%) | catalogued as rs760925109; called by mutect2, varscan2
- IQCC | c.558+2T>C p.X186_splice | Splice Site (SNP) | VAF 8/50 reads (16%) | catalogued as COSV52207425; called by muse, mutect2, varscan2
- IQGAP1 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV51582074; called by muse, mutect2, varscan2
- IRAG1 | c.971G>A p.G324D | Missense Mutation (SNP) | VAF 37/328 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs758893178, COSV70213086; called by muse, mutect2, varscan2
- KALRN | c.6767C>T p.A2256V (on ENST00000360013 / NM_001024660.4; = p.A559V on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/277 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as rs940946966; called by muse, mutect2
- KAT14 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs754597088, COSV66607677; called by muse, mutect2, varscan2
- KCNH7 | c.2104G>A p.E702K | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs767012676, COSV100036086; called by muse, mutect2, varscan2
- KCNH7 | c.250C>A p.Q84K | Missense Mutation (SNP) | VAF 41/230 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.17); catalogued as COSV100036190; called by muse, mutect2, varscan2
- KDM4B | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.325); catalogued as rs900640500, COSV50229176; called by muse, mutect2, varscan2
- KIF23 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV52979411; called by muse, mutect2, varscan2
- KIF2A | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs1007319532; called by muse, mutect2
- KLHDC7B | c.452C>T p.S151L (on ENST00000395676; = p.S792L on NM_138433.5) | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs762445861; called by muse, varscan2
- KMT2C | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 19/333 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV51436128; called by muse, mutect2
- KRI1 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs371805885, COSV57264327; called by muse, varscan2
- LAMB2 | c.3110-6G>A | Splice Region (SNP) | VAF 36/466 reads (8%) | catalogued as rs1560072686; called by muse, mutect2
- LAMB4 | c.5013dup p.Q1672Tfs*8 | Frame Shift Ins (INS) | VAF 14/83 reads (17%) | catalogued as rs774297152; called by mutect2, pindel, varscan2
- LCP2 | c.440C>G p.P147R | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99252860; called by muse, mutect2, varscan2
- LIG1 | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 12/339 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99618777; called by muse, mutect2
- LILRA4 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV52493754; called by muse, mutect2, varscan2
- LMX1B | c.755T>A p.L252Q | Missense Mutation (SNP) | VAF 25/586 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as CM992925; called by muse, mutect2
- LRFN2 | c.1175C>A p.P392H | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.615); catalogued as rs143225218, COSV57836025; called by muse, mutect2, varscan2
- LRP1B | c.875G>T p.W292L | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101259127, COSV67199918; called by muse, mutect2, varscan2
- LRRK1 | c.3626C>T p.P1209L | Missense Mutation (SNP) | VAF 71/320 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs774546820, COSV52620414; called by muse, mutect2, varscan2
- LTBP1 | c.3145G>A p.A1049T (on ENST00000404816 / NM_206943.4; = p.A723T on NM_000627.4) | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs200895398, COSV55379111; called by muse, mutect2
- MACF1 | c.20518G>A p.D6840N (on ENST00000372915; = p.D4885N on NM_012090.5) | Missense Mutation (SNP) | VAF 41/231 reads (18%) | catalogued as rs769550602, COSV57129886, COSV57137881; called by muse, mutect2, varscan2
- MARK2 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 14/409 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1452634071; called by muse, mutect2
- MCM3 | c.1286G>A p.R429H (on ENST00000229854 / NM_001366374.2; = p.R419H on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/376 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758287245; called by muse, mutect2
- MDM2 | c.359-1G>C p.X120_splice | Splice Site (SNP) | VAF 17/97 reads (18%) | catalogued as COSV50700350; called by muse, mutect2, varscan2
- MDN1 | c.15469G>A p.A5157T | Missense Mutation (SNP) | VAF 16/235 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs762901999; called by muse, mutect2
- MED12 | c.967C>T p.Q323* | Nonsense Mutation (SNP) | VAF 25/132 reads (19%) | catalogued as COSV61332513, COSV61345235; called by muse, mutect2, varscan2
- METTL15 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs536139864; called by muse, mutect2, varscan2
- MIB1 | c.1979A>G p.D660G | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1260356230; called by muse, mutect2, varscan2
- MICOS13 | c.259+6G>A | Splice Region (SNP) | VAF 7/81 reads (9%) | catalogued as rs1380806286; called by muse, mutect2
- MOS | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.021); catalogued as COSV61336115; called by muse, mutect2
- MROH2B | c.1213A>G p.T405A | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs748910666; called by muse, mutect2, varscan2
- MTERF2 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as rs758134906, COSV53527070; called by muse, varscan2
- MUC5B | c.8921C>A p.T2974N | Missense Mutation (SNP) | VAF 76/357 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV101500282; called by muse, mutect2, varscan2
- MYH14 | c.10G>A p.V4M | Missense Mutation (SNP) | VAF 63/290 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs532458856, COSV51836643; called by muse, mutect2, varscan2
- MYH2 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.909); catalogued as rs141174023, COSV55437252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCSTN | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 32/298 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1325765596; called by muse, mutect2, varscan2
- NHS | c.3340C>A p.P1114T | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66282589; called by muse, mutect2, varscan2
- NLRP5 | c.979A>G p.K327E | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs770259115; called by muse, mutect2, varscan2
- NR2F6 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 39/682 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV99360066; called by muse, mutect2
- NRIP1 | c.281A>T p.N94I | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs1416332382; called by muse, mutect2, varscan2
- NSD1 | c.4036G>T p.E1346* | Nonsense Mutation (SNP) | VAF 27/101 reads (27%) | catalogued as COSV61775101; called by muse, mutect2, varscan2
- NUP93 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs34670294; called by muse, mutect2, varscan2
- OBSCN | c.2038del p.A680Rfs*3 | Frame Shift Del (DEL) | VAF 42/233 reads (18%) | catalogued as COSV52822012; called by mutect2, pindel, varscan2
- OR10AG1 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100400276; called by muse, mutect2, varscan2
- OR2L8 | c.455C>A p.S152* | Nonsense Mutation (SNP) | VAF 24/127 reads (19%) | catalogued as COSV61726895; called by muse, mutect2, varscan2
- OR2T35 | c.710C>A p.A237D | Missense Mutation (SNP) | VAF 66/399 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs764289234; called by muse, mutect2, varscan2
- OR4A15 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.58); catalogued as COSV59034160; called by muse, mutect2, varscan2
- OR52K2 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as rs750840213, COSV57835623; called by muse, mutect2
- OR56A5 | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.027); catalogued as rs565433193, COSV60828091; called by muse, mutect2, varscan2
- OR5B21 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs755739117, COSV64482058; called by muse, mutect2, varscan2
- OR5J2 | c.431T>A p.L144H | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56621412; called by muse, mutect2, varscan2
- OR5R1 | c.602C>G p.A201G | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV56571502; called by muse, mutect2, varscan2
- OR6T1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs368321030; called by muse, mutect2, varscan2
- OR8G1 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.12); catalogued as rs375286590, COSV58383363; called by muse, mutect2, varscan2
- OR9I1 | c.104A>C p.Y35S | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100109435; called by muse, mutect2, varscan2
- OR9Q2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 19/219 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs1384301145; called by muse, mutect2
- P2RX6 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs990531769, COSV60385170; called by muse, mutect2
- PAPLN | c.1825G>A p.A609T (on ENST00000554301; = p.A582T on NM_173462.4) | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs533204134, COSV53714764; called by muse, mutect2, varscan2
- PARPBP | c.1264-2A>G p.X422_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | catalogued as COSV59673648; called by muse, mutect2, varscan2
- PCDHA6 | c.823G>T p.G275W | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100972073; called by muse, mutect2, varscan2
- PCDHGA1 | c.1868C>T p.T623M | Missense Mutation (SNP) | VAF 64/422 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs373798096; called by muse, mutect2, varscan2
- PCLO | c.3683G>A p.R1228H | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.172); catalogued as rs765796028, COSV100438351; called by muse, mutect2
- PDGFB | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.813); catalogued as rs190122588, COSV58650312; called by muse, mutect2, varscan2
- PHLDB1 | c.1621G>A p.A541T | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as rs782005327; called by muse, mutect2, varscan2
- PIEZO2 | c.4609C>T p.R1537W | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1341123204; called by muse, mutect2
- PIK3CG | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs200423506; called by muse, mutect2
- PIK3CG | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 54/255 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV63247193; called by muse, mutect2, varscan2
- PKP3 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773167699, COSV58986586; called by muse, mutect2, varscan2
- PLXNA3 | c.1203C>G p.I401M | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV63754768; called by muse, mutect2, varscan2
- PRDM5 | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 75/298 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.342); catalogued as rs763208055, COSV53367439; called by muse, mutect2, varscan2
- PRIMA1 | c.43T>C p.S15P | Missense Mutation (SNP) | VAF 106/625 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1416173462; called by muse, mutect2, varscan2
- PRRC2B | c.3439C>T p.R1147C | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774089087; called by muse, mutect2, varscan2
- PSMD8 | c.10A>T p.K4* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as rs748688347; called by muse, varscan2
- PTPRN | c.1811C>A p.A604E | Missense Mutation (SNP) | VAF 94/552 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as COSV55351490; called by muse, mutect2, varscan2
- PUS1 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 56/317 reads (18%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs758584053, COSV59034693; called by muse, mutect2, varscan2
- RAC2 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as rs758461304, COSV99969611; ClinVar: likely benign; called by muse, mutect2, varscan2
- RB1 | c.2212-2A>C p.X738_splice | Splice Site (SNP) | VAF 18/54 reads (33%) | catalogued as CS083262, COSV57307485, COSV99926008; called by muse, mutect2, varscan2
- RBAK | c.397A>C p.I133L | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV62331773; called by muse, mutect2, varscan2
- RBM26 | c.271G>C p.G91R | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.367); catalogued as COSV57400794; called by muse, mutect2, varscan2
- RBP3 | c.2101G>C p.V701L | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs781920668; called by muse, mutect2, varscan2
- RECK | c.1093G>C p.E365Q | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV65035059; called by muse, mutect2, varscan2
- REG3A | c.110G>T p.R37L | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs138199548; called by muse, mutect2, varscan2
- RFXAP | c.359del p.G120Afs*18 | Frame Shift Del (DEL) | VAF 26/100 reads (26%) | catalogued as rs1224857205; called by mutect2, pindel, varscan2
- RHBG | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV54805679, COSV54807935; called by muse, mutect2, varscan2
- RHO | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 66/480 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs118173887, CM1211096; called by muse, mutect2, varscan2
- RIMBP2 | c.3138G>T p.K1046N | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as COSV55464422; called by muse, mutect2, varscan2
- RIN3 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs753665702; called by muse, varscan2
- RPGR | c.1687G>A p.V563M | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as rs148334278, COSV58834440; called by muse, mutect2, varscan2
- RTL1 | c.3941C>A p.A1314E | Missense Mutation (SNP) | VAF 46/323 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs1388814486; called by muse, mutect2, varscan2
- RYR2 | c.1951C>T p.H651Y | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs759839219, COSV100772007; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.11110G>A p.E3704K (on ENST00000389232; = p.E3705K on NM_001036.6) | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1204301579; called by muse, mutect2, varscan2
- SASH1 | c.921C>A p.Y307* | Nonsense Mutation (SNP) | VAF 30/141 reads (21%) | catalogued as COSV66565744; called by muse, mutect2
- SCAP | c.1710dup p.S571Qfs*13 | Frame Shift Ins (INS) | VAF 10/74 reads (14%) | catalogued as rs1229536681; called by mutect2, varscan2
- SCLT1 | c.186G>C p.E62D | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV55410386; called by muse, mutect2
- SCN10A | c.3529G>A p.D1177N | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV71861708; called by muse, mutect2, varscan2
- SCYL1 | c.2368C>T p.R790C | Missense Mutation (SNP) | VAF 37/285 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1209439165; called by muse, mutect2, varscan2
- SELENOO | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 48/431 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs570193944, COSV66598410; called by muse, mutect2, varscan2
- SEMA6D | c.2483T>C p.I828T (on ENST00000316364 / NM_153618.2; = p.I766T on NM_020858.2) | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as rs1379333473; called by muse, mutect2, varscan2
- SH3RF3 | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs954063541; called by muse, mutect2, varscan2
- SIN3B | c.2276T>C p.L759P | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs866589325; called by muse, mutect2, varscan2
- SIX5 | c.1570G>A p.G524S | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.113); catalogued as rs1177206901; called by muse, mutect2
- SLAIN1 | c.1052A>G p.H351R (on ENST00000466548; = p.H88R on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1373673178; called by muse, mutect2, varscan2
- SLC16A14 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1205196087, COSV54617922; called by muse, mutect2, varscan2
- SLC17A8 | c.187C>G p.P63A | Missense Mutation (SNP) | VAF 64/296 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as rs778910826; called by muse, mutect2, varscan2
- SLC22A3 | c.857+1G>T p.X286_splice | Splice Site (SNP) | VAF 18/131 reads (14%) | catalogued as COSV99278829; called by muse, mutect2, varscan2
- SLC7A13 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.621); catalogued as COSV52537214, COSV99879142; called by muse, mutect2, varscan2
- SLC7A13 | c.661G>T p.G221W | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.083); catalogued as COSV99879145; called by muse, mutect2, varscan2
- SMARCE1 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as COSV100795929; called by muse, mutect2, varscan2
- SNRNP70 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99672588; called by muse, mutect2
- SOGA3 | c.2069C>T p.A690V | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.617); catalogued as COSV64104967; called by muse, mutect2
- SRSF4 | c.1322G>C p.R441P | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.204); catalogued as COSV65695477; called by muse, mutect2, varscan2
- STAB2 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.114); catalogued as rs745609486; called by muse, mutect2, varscan2
- TBX18 | c.692C>G p.S231W | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63736561; called by muse, mutect2, varscan2
- TDRD9 | c.2202_2203dup p.K735Ifs*31 | Frame Shift Ins (INS) | VAF 10/57 reads (18%) | catalogued as rs770114590; called by mutect2, varscan2
- TMEM132B | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 19/203 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.085); catalogued as rs757718701, COSV54749643; called by muse, mutect2
- TMEM167A | c.117G>T p.L39F | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1004479373; called by muse, mutect2, varscan2
- TNFSF8 | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56342525; called by muse, mutect2, varscan2
- TPM2 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 82/472 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as CM1213074; called by muse, varscan2
- TRIOBP | c.7079G>A p.R2360H (on ENST00000644935 / NM_001039141.3; = p.R647H on NM_007032.5) | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.06); catalogued as rs373460457; called by muse, mutect2
- TTC27 | c.700C>T p.H234Y | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs760457238, COSV58651982; called by muse, mutect2, varscan2
- TTLL3 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 42/281 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.063); catalogued as rs770396917; called by muse, mutect2, varscan2
- TTN | c.16492G>T p.A5498S (on ENST00000591111; = p.A4571S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | PolyPhen probably damaging (0.996); catalogued as COSV60404097; called by muse, mutect2
- TWF2 | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as COSV59726670; called by muse, mutect2, varscan2
- UBR4 | c.6820del p.T2274Qfs*12 | Frame Shift Del (DEL) | VAF 21/159 reads (13%) | catalogued as COSV64387571; called by mutect2, pindel, varscan2
- UBR4 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.885); catalogued as rs373897497; called by muse, mutect2
- UCN3 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 23/263 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs782142877; called by muse, mutect2
- UROC1 | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 41/402 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52037254; called by muse, varscan2
- VPS45 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 20/123 reads (16%) | catalogued as COSV64888921; called by muse, mutect2, varscan2
- WASHC4 | c.656T>C p.M219T | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.141); catalogued as rs201153364; called by muse, mutect2, varscan2
- WDPCP | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 30/275 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55420984; called by muse, mutect2, varscan2
- WDR93 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs376704792, COSV99175872; called by muse, mutect2, varscan2
- WSCD1 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 93/357 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as rs778038699, COSV58496176; called by muse, mutect2, varscan2
- ZFP82 | c.1048C>T p.R350* | Nonsense Mutation (SNP) | VAF 19/100 reads (19%) | catalogued as rs375259952; called by muse, mutect2, varscan2
- ZNF155 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs914757685; called by muse, mutect2
- ZNF174 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 54/277 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1341234345, COSV99237731; called by muse, mutect2, varscan2
- ZNF219 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1309131368; called by muse, mutect2
- ZNF302 | c.277C>G p.L93V (on ENST00000627982; = p.L92V on NM_018675.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV71063707; called by muse, mutect2
- ZNF425 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as rs772588914; called by muse, mutect2
- ZNF713 | c.1171G>T p.G391W (on ENST00000633730 / NM_001366796.2; = p.G404W on NM_182633.3) | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV70057208; called by muse, mutect2, varscan2
- ZNF777 | c.2282G>A p.R761H | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV56098406; called by muse, mutect2
- ZNF81 | c.1537C>T p.L513F | Missense Mutation (SNP) | VAF 19/249 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58575608; called by muse, mutect2
- ZNF841 | c.2160G>T p.L720F (on ENST00000426391 / NM_001369830.1; = p.L836F on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs770538217; called by muse, mutect2, varscan2
- ZPR1 | c.1219G>T p.D407Y | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1305549507; called by muse, mutect2, varscan2
- AARS2 | c.952G>T p.D318Y | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- AASDH | c.2564C>T p.A855V | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- ABCB1 | c.2173C>A p.Q725K | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- ABCB4 | c.136-2A>T p.X46_splice | Splice Site (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- ABCB7 | c.1530-7A>T | Splice Region (SNP) | VAF 9/118 reads (8%) | called by muse, mutect2
- ABCC12 | c.3470G>A p.G1157D | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAMTS6 | c.3245-1G>C p.X1082_splice | Splice Site (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- ADAMTSL2 | c.1286T>C p.V429A | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCK5 | c.1711G>A p.A571T | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRF3 | c.377T>A p.V126D (on ENST00000311519 / NM_001145168.1; = p.V67D on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/263 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- ALLC | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by mutect2, varscan2
- ALMS1 | c.11919G>C p.K3973N | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ALPK2 | c.6373T>C p.C2125R | Missense Mutation (SNP) | VAF 30/247 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD9 | c.896T>A p.L299Q | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ARFGAP1 | c.548A>T p.Y183F | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- ARHGEF2 | c.574G>A p.D192N (on ENST00000361247 / NM_001162383.2; = p.D165N on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ARRDC2 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 93/513 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- ARX | c.163A>T p.T55S | Missense Mutation (SNP) | VAF 28/756 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- ASB9 | c.588del p.G198Vfs*61 (on ENST00000380488 / NM_001031739.3; = p.G198Vfs*118 on NM_024087.3) | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | called by mutect2, pindel, varscan2
- ASNS | c.1529C>G p.P510R | Missense Mutation (SNP) | VAF 35/223 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASPHD1 | c.1105C>A p.L369I | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ATG4B | c.577A>T p.T193S | Missense Mutation (SNP) | VAF 105/458 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATRNL1 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AVIL | c.1712C>T p.A571V | Missense Mutation (SNP) | VAF 48/228 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- B4GALT7 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCL6B | c.383A>G p.H128R | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2
- BMF | c.363del p.E122Kfs*51 | Frame Shift Del (DEL) | VAF 46/238 reads (19%) | called by mutect2, pindel, varscan2
- BMPR2 | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.473); called by muse, mutect2
- BRINP1 | c.782A>T p.Q261L | Missense Mutation (SNP) | VAF 64/374 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- BTBD19 | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 24/590 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.03); called by muse, mutect2
- BTNL2 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 90/454 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- C17orf98 | c.360A>T p.K120N | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2
- C1QTNF3 | c.259G>T p.G87C | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1orf131 | c.104A>T p.N35I | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- C1orf162 | c.240G>T p.L80F | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- C1orf94 | c.1408C>T p.P470S (on ENST00000488417 / NM_001134734.2; = p.P280S on NM_032884.5) | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- C3 | c.1839G>T p.Q613H | Missense Mutation (SNP) | VAF 95/443 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C9orf40 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.237); called by muse, mutect2
- CACNA1C | c.3033G>T p.R1011S | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CACNA1E | c.3141C>A p.S1047R | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CAVIN2 | c.273G>T p.K91N | Missense Mutation (SNP) | VAF 67/413 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- CCDC88C | c.4203-1G>T p.X1401_splice | Splice Site (SNP) | VAF 41/279 reads (15%) | called by muse, mutect2, varscan2
- CDC14C | c.1579C>T p.P527S (on ENST00000428251; = p.P420S on NM_152627.3) | Missense Mutation (SNP) | VAF 35/291 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDC42BPG | c.3222_3234del p.R1074Sfs*59 | Frame Shift Del (DEL) | VAF 50/422 reads (12%) | called by mutect2, pindel
- CDK11B | c.185T>C p.I62T | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CDK16 | c.410A>G p.N137S | Missense Mutation (SNP) | VAF 56/304 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDK5RAP2 | c.3848A>G p.E1283G | Missense Mutation (SNP) | VAF 17/337 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2
- CFAP57 | c.492G>T p.Q164H | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CFAP70 | c.944C>A p.P315H | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- CGB7 | c.470C>A p.P157H | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- CHMP2A | c.349-18_372del p.X117_splice | Splice Site (DEL) | VAF 54/264 reads (20%) | called by mutect2, pindel
- CHRM1 | c.578C>A p.A193D | Missense Mutation (SNP) | VAF 75/321 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CLTRN | c.377T>G p.L126* | Nonsense Mutation (SNP) | VAF 38/145 reads (26%) | called by muse, mutect2, varscan2
- CLUAP1 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CMYA5 | c.6715T>A p.S2239T | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CNTNAP2 | c.3413T>A p.L1138Q | Missense Mutation (SNP) | VAF 58/330 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- COBL | c.3536G>T p.S1179I | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- COBL | c.1187G>A p.S396N | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- COL12A1 | c.3799G>A p.A1267T | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- COL15A1 | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 60/393 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- COL4A2 | c.4221G>T p.Q1407H | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- COL4A3 | c.4169G>T p.R1390I | Missense Mutation (SNP) | VAF 49/267 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- COL4A4 | c.1588G>T p.G530* | Nonsense Mutation (SNP) | VAF 67/335 reads (20%) | called by muse, mutect2, varscan2
- COX18 | c.191T>C p.V64A | Missense Mutation (SNP) | VAF 46/556 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.38); called by muse, mutect2
- CPLX1 | c.81C>A p.D27E | Missense Mutation (SNP) | VAF 44/231 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CRK | c.185_187del p.I62del | In Frame Del (DEL) | VAF 54/226 reads (24%) | called by pindel, varscan2
- CRTC2 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- CSNK1A1 | c.74C>A p.S25Y | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- CTNND2 | c.1864G>T p.G622W | Missense Mutation (SNP) | VAF 18/454 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CTRC | c.304G>T p.V102L | Missense Mutation (SNP) | VAF 102/507 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CYTH4 | c.4G>C p.D2H | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- CYTH4 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- DAPK1 | c.2382G>T p.K794N | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); called by mutect2, varscan2
- DBR1 | c.632C>G p.S211* | Nonsense Mutation (SNP) | VAF 25/163 reads (15%) | called by muse, mutect2, varscan2
- DCAF11 | c.967C>A p.L323M | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2
- DDX50 | c.2153G>C p.R718T | Missense Mutation (SNP) | VAF 61/264 reads (23%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- DGKB | c.1567C>T p.L523F | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DMD | c.7804A>G p.K2602E | Missense Mutation (SNP) | VAF 19/236 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2
- DMRTA2 | c.487G>C p.A163P | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- DNAH3 | c.8038C>A p.L2680M | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.315); called by muse, mutect2
- DNAH6 | c.2077-1G>T p.X693_splice | Splice Site (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2, varscan2
- DOCK11 | c.5209C>G p.Q1737E | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.82); PolyPhen benign (0.013); called by muse, mutect2
- DOCK11 | c.5851G>A p.V1951I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.238); called by muse, mutect2
- DPY19L2P2 | n.681C>T | Splice Region (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- DSG1 | c.194C>G p.S65* | Nonsense Mutation (SNP) | VAF 28/278 reads (10%) | called by muse, mutect2
- EFHC2 | c.1955dup p.N652Kfs*9 | Frame Shift Ins (INS) | VAF 21/116 reads (18%) | called by mutect2, pindel, varscan2
- EIF3E | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- EP400 | c.3794A>T p.Q1265L | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- EPHA10 | c.2758C>A p.P920T | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ERCC6L | c.1969G>T p.D657Y | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- F8 | c.5231G>T p.G1744V | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.218); called by muse, mutect2
- FAIM | c.454A>G p.K152E | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- FAM111A | c.434G>C p.S145T | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM43B | c.415C>T p.H139Y | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- FBXL4 | c.1385T>C p.V462A | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- FEM1A | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- FLT4 | c.1040C>A p.A347E | Missense Mutation (SNP) | VAF 47/273 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- FMO4 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FOXI3 | c.1003C>G p.P335A | Missense Mutation (SNP) | VAF 94/532 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FREM1 | c.4282G>T p.E1428* | Nonsense Mutation (SNP) | VAF 17/118 reads (14%) | called by muse, mutect2, varscan2
- FRMPD4 | c.2327C>A p.S776* | Nonsense Mutation (SNP) | VAF 71/207 reads (34%) | called by muse, mutect2, varscan2
- FZD6 | c.324dup p.L109Ifs*3 | Frame Shift Ins (INS) | VAF 22/135 reads (16%) | called by mutect2, pindel, varscan2
- FZD6 | c.924C>G p.F308L | Missense Mutation (SNP) | VAF 60/382 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- GAK | c.1699C>T p.P567S | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- GBA2 | c.1839T>A p.D613E | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- GDPD2 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GGT7 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GJA1 | c.309A>T p.E103D | Missense Mutation (SNP) | VAF 62/282 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- GLDC | c.1341G>T p.K447N | Missense Mutation (SNP) | VAF 81/389 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GMPPA | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GNL3L | c.554A>G p.K185R | Missense Mutation (SNP) | VAF 20/243 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.073); called by muse, mutect2
- GOLGA8S | c.269C>A p.S90Y | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.337); called by mutect2, varscan2
- GPR119 | c.943C>A p.P315T | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GRID1 | c.1394G>T p.G465V | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- GRIK1 | c.2144C>G p.S715C | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2
- GRIK4 | c.2261C>G p.P754R | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIP1 | c.2247G>C p.L749F (on ENST00000359742 / NM_001379345.1; = p.L697F on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GRM1 | c.902G>A p.S301N | Missense Mutation (SNP) | VAF 63/341 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- H2BC15 | c.122A>G p.Y41C | Missense Mutation (SNP) | VAF 85/445 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HCN1 | c.1405C>G p.L469V | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- HDAC6 | c.1850C>G p.A617G | Missense Mutation (SNP) | VAF 57/257 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- HENMT1 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2
- HOXA2 | c.392-5C>T | Splice Region (SNP) | VAF 98/447 reads (22%) | called by muse, mutect2, varscan2
- HOXB3 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HSPH1 | c.2471dup p.E825Gfs*13 | Frame Shift Ins (INS) | VAF 15/91 reads (16%) | called by mutect2, pindel, varscan2
- HTR2A | c.1214C>A p.P405Q | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- HTT | c.6462T>A p.S2154R | Missense Mutation (SNP) | VAF 69/333 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HTT | c.7351T>C p.Y2451H | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- HUWE1 | c.2813G>A p.S938N | Missense Mutation (SNP) | VAF 21/212 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); called by muse, mutect2
- HYAL3 | c.961dup p.D321Gfs*8 | Frame Shift Ins (INS) | VAF 23/239 reads (10%) | called by mutect2, pindel
- IFNAR1 | c.77-2A>T p.X26_splice | Splice Site (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2
- IGKV1D-33 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 20/187 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- IGKV3-20 | c.243C>A p.D81E | Missense Mutation (SNP) | VAF 81/444 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- IL1RAPL1 | c.377G>T p.C126F | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL1RAPL1 | c.1257G>T p.W419C | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.943); called by mutect2, varscan2
- INMT-MINDY4 | c.419G>A p.G140D | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- INSC | c.595A>G p.R199G | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- IQCA1 | c.2087A>G p.Y696C | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IRF2BP2 | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- IRGQ | c.1796G>T p.G599V | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT tolerated (0.39); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ISL2 | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.94); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KAT2B | c.727A>T p.T243S | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- KCNK18 | c.766C>A p.L256M | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- KCNQ2 | c.1171C>A p.L391M (on ENST00000359125 / NM_172107.4; = p.L381M on NM_004518.6) | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIAA1671 | c.3352G>T p.D1118Y | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- KLHL13 | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.02); called by muse, mutect2
- KPNA6 | c.833A>G p.Y278C | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KRTAP10-6 | c.761C>G p.S254C | Missense Mutation (SNP) | VAF 154/902 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- LAS1L | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 72/312 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- LDB3 | c.1439del p.G480Afs*12 | Frame Shift Del (DEL) | VAF 33/146 reads (23%) | called by mutect2, pindel, varscan2
- LEMD1 | c.99G>T p.L33F | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- LLGL2 | c.1729T>G p.F577V | Missense Mutation (SNP) | VAF 18/449 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- LMO7 | c.1216C>G p.L406V (on ENST00000357063; = p.L136V on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRFN2 | c.2072_2102del p.H691Pfs*84 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | called by mutect2, pindel
- LRP4 | c.570del p.C191Afs*206 | Frame Shift Del (DEL) | VAF 27/140 reads (19%) | called by mutect2, pindel
- LRPPRC | c.1229C>T p.T410I | Missense Mutation (SNP) | VAF 51/272 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- LRRC14 | c.814A>G p.N272D | Missense Mutation (SNP) | VAF 60/339 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LRRC37A3 | c.3268G>A p.E1090K | Missense Mutation (SNP) | VAF 80/321 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRC4C | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.718); called by muse, varscan2
- LTN1 | c.1561G>T p.V521L | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MAGEB1 | c.529C>A p.L177I | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- MAGEB1 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 57/243 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAMLD1 | c.2198C>A p.T733N | Missense Mutation (SNP) | VAF 21/442 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.294); called by muse, mutect2
- MAOB | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 35/169 reads (21%) | called by muse, mutect2, varscan2
- MARCO | c.1103T>A p.V368D | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- MARK1 | c.1312A>G p.K438E | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2
- MCM5 | c.596+2T>C p.X199_splice | Splice Site (SNP) | VAF 22/141 reads (16%) | called by muse, mutect2, varscan2
- MDC1 | c.2031T>A p.H677Q | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.08); PolyPhen benign (0.055); called by muse, varscan2
- MED13L | c.2815C>T p.P939S | Missense Mutation (SNP) | VAF 28/366 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- MFAP3L | c.753G>T p.R251S | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MMP17 | c.652A>T p.T218S | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MMP20 | c.1198C>A p.L400I | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.055); called by muse, mutect2
- MOV10 | c.1693C>G p.Q565E | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, varscan2
- MPL | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 45/387 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- MTHFS | c.445G>T p.G149C | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC16 | c.33860G>A p.S11287N | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- MXRA5 | c.707G>T p.R236I | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- MYH3 | c.4027C>A p.L1343M | Missense Mutation (SNP) | VAF 22/488 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2
- NADK | c.959C>T p.T320I | Missense Mutation (SNP) | VAF 30/435 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NAV3 | c.6716-1G>T p.X2239_splice (on ENST00000397909 / NM_001024383.2; = p.X2217_splice on NM_014903.6) | Splice Site (SNP) | VAF 4/26 reads (15%) | called by mutect2, varscan2
- NDN | c.70A>G p.S24G | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- NDST3 | c.224G>T p.R75M | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- NEB | c.9325G>T p.D3109Y | Missense Mutation (SNP) | VAF 55/278 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NF1 | c.914A>T p.K305I | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- NHS | c.3341C>A p.P1114Q | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NHSL1 | c.1175G>T p.R392I | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- NIPBL | c.587C>G p.T196R | Missense Mutation (SNP) | VAF 43/237 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- NLGN1 | c.1861C>G p.Q621E | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- NMRAL1 | c.772G>T p.A258S | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); called by muse, mutect2
- NOTCH3 | c.6551C>G p.S2184W | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- NPVF | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NRCAM | c.3499C>G p.Q1167E (on ENST00000379028 / NM_001371124.1; = p.Q1046E on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- NT5C2 | c.1575_1576del p.R526Vfs*3 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | called by pindel, varscan2
- OCSTAMP | c.1418G>T p.R473I | Missense Mutation (SNP) | VAF 57/312 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ONECUT2 | c.587C>A p.T196N | Missense Mutation (SNP) | VAF 46/268 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, varscan2
- OOEP | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- OPHN1 | c.1584T>A p.F528L | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OPRK1 | c.431C>G p.T144S | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR10V1 | c.882G>T p.R294S | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- OR13C4 | c.5A>G p.D2G | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- OR2T27 | c.499C>G p.P167A | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); called by mutect2, varscan2
- OR5V1 | c.434C>A p.A145E | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- OR7C1 | c.286G>C p.G96R | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- OR7G3 | c.284C>A p.T95K | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR8K3 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.023); called by muse, mutect2
- OXR1 | c.1426G>C p.E476Q (on ENST00000442977 / NM_001198532.1; = p.E475Q on NM_018002.3) | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PALM | c.443-1G>T p.X148_splice | Splice Site (SNP) | VAF 14/76 reads (18%) | called by muse, mutect2, varscan2
- PANK3 | c.512G>C p.R171P | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PARP10 | c.2970C>G p.I990M | Missense Mutation (SNP) | VAF 79/436 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PARP10 | c.2281_2282del p.S761Cfs*6 | Frame Shift Del (DEL) | VAF 61/391 reads (16%) | called by mutect2, pindel, varscan2
- PARP12 | c.875G>C p.R292T | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- PCDH19 | c.1760T>C p.V587A | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- PCDH9 | c.1768A>T p.T590S | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHB1 | c.1765A>C p.K589Q | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB4 | c.2044G>T p.A682S | Missense Mutation (SNP) | VAF 128/465 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- PCDHGA7 | c.2346G>T p.Q782H | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PCDHGC4 | c.2330C>T p.S777F | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCLO | c.6194A>T p.Y2065F | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- PCNX3 | c.857G>T p.G286V | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCSK9 | c.1339A>T p.S447C | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- PCYT1B | c.480del p.K160Nfs*26 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel
- PDCL3 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 19/115 reads (17%) | called by muse, mutect2, varscan2
- PDX1 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDZRN4 | c.2172_2174del p.I724del (on ENST00000402685 / NM_001164595.2; = p.I466del on NM_013377.4) | In Frame Del (DEL) | VAF 29/223 reads (13%) | called by pindel, varscan2
- PI4KA | c.756G>C p.K252N | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PIEZO2 | c.431T>C p.V144A | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- PIF1 | c.1575C>A p.H525Q | Missense Mutation (SNP) | VAF 84/439 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PKN3 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 63/368 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PLCH2 | c.3760T>A p.S1254T | Missense Mutation (SNP) | VAF 37/556 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- PODXL2 | c.549G>T p.E183D | Missense Mutation (SNP) | VAF 41/257 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- POLR1B | c.899T>C p.V300A | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.08); called by muse, mutect2
- POM121L2 | c.1285A>G p.S429G | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- PORCN | c.373+3A>G | Splice Region (SNP) | VAF 16/426 reads (4%) | called by muse, mutect2
- POU6F2 | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPFIA2 | c.1448A>T p.H483L | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- PPP3R2 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 65/339 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- PRKDC | c.12121del p.R4041Dfs*11 | Frame Shift Del (DEL) | VAF 23/128 reads (18%) | called by mutect2, pindel, varscan2
- PRMT6 | c.38del p.G13Afs*48 | Frame Shift Del (DEL) | VAF 7/69 reads (10%) | called by mutect2, pindel
- PRMT6 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PROX1 | c.292A>T p.K98* | Nonsense Mutation (SNP) | VAF 13/113 reads (12%) | called by muse, mutect2, varscan2
- PRR7 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 112/448 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRR7 | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- PTPN11 | c.513G>C p.M171I | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- PTPRC | c.16T>C p.W6R | Missense Mutation (SNP) | VAF 56/289 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PTPRM | c.4170G>C p.L1390F | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPRS | c.3520G>T p.G1174C | Missense Mutation (SNP) | VAF 51/253 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- PTPRZ1 | c.747del p.F249Lfs*29 | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | called by mutect2, pindel, varscan2
- RAB35 | c.104-2A>T p.X35_splice | Splice Site (SNP) | VAF 20/153 reads (13%) | called by muse, mutect2, varscan2
- RAD21L1 | c.431G>T p.R144I | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- RAD9B | c.614A>G p.H205R | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RASD2 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 11/236 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RBL2 | c.818dup p.C274Lfs*4 | Frame Shift Ins (INS) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- RECQL4 | c.3394-1G>T p.X1132_splice | Splice Site (SNP) | VAF 57/311 reads (18%) | called by muse, mutect2, varscan2
- REG1B | c.250G>T p.V84L | Missense Mutation (SNP) | VAF 39/270 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RGS7BP | c.689G>A p.S230N | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- RIMS2 | c.3529A>C p.T1177P | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIT2 | c.391del p.V131Wfs*19 | Frame Shift Del (DEL) | VAF 15/91 reads (16%) | called by mutect2, pindel, varscan2
- RMDN3 | c.52C>G p.L18V | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- RNF40 | c.2888G>T p.C963F | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- RPGRIP1 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 15/92 reads (16%) | called by muse, mutect2, varscan2
- RPL10L | c.559A>G p.K187E | Missense Mutation (SNP) | VAF 15/189 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RPL4 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 15/178 reads (8%) | called by muse, mutect2
- RYR2 | c.6056del p.G2019Efs*5 | Frame Shift Del (DEL) | VAF 14/81 reads (17%) | called by mutect2, pindel, varscan2
- RYR3 | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RYR3 | c.10472G>A p.R3491K (on ENST00000389232; = p.R3492K on NM_001036.6) | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SAMD7 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SAMD9 | c.4344A>T p.Q1448H | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- SCLT1 | c.187T>A p.Y63N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SCN1A | c.1317G>C p.Q439H | Missense Mutation (SNP) | VAF 30/341 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2
- SCN5A | c.4717G>A p.G1573S (on ENST00000333535 / NM_198056.3; = p.G1572S on NM_000335.5) | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- SCP2D1 | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 20/76 reads (26%) | called by muse, mutect2
- SDR9C7 | c.791T>A p.M264K | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- SEC23A | c.1429G>T p.G477C | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- SEMA6D | c.2021del p.L674Wfs*44 (on ENST00000316364 / NM_153618.2; = p.L612Wfs*44 on NM_020858.2) | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel, varscan2
- SERBP1 | c.1206G>T p.E402D (on ENST00000370995 / NM_001018067.2; = p.E381D on NM_015640.4) | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SERPINA12 | c.1109G>T p.G370V | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SERPINA12 | c.1108G>T p.G370C | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- SH3KBP1 | c.1739C>G p.T580R | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SIGLEC10 | c.916C>A p.L306M | Missense Mutation (SNP) | VAF 41/373 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SIM1 | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 33/230 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIPA1L2 | c.5094G>T p.E1698D | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- SLAMF9 | c.577dup p.D193Gfs*24 | Frame Shift Ins (INS) | VAF 52/456 reads (11%) | called by mutect2, pindel, varscan2
- SLC10A3 | c.53del p.G18Afs*9 | Frame Shift Del (DEL) | VAF 56/298 reads (19%) | called by mutect2, varscan2
- SLC22A10 | c.1334C>A p.S445Y | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.934); called by muse, mutect2
- SLC22A11 | c.344A>T p.D115V | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC2A9 | c.991G>T p.G331C | Missense Mutation (SNP) | VAF 44/235 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC39A11 | c.835T>G p.F279V (on ENST00000542342 / NM_001159770.2; = p.F272V on NM_139177.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/262 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SLC45A1 | c.667A>T p.S223C | Missense Mutation (SNP) | VAF 90/430 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SLC6A13 | c.1511G>A p.C504Y | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC9A5 | c.1750C>T p.Q584* | Nonsense Mutation (SNP) | VAF 34/210 reads (16%) | called by muse, mutect2, varscan2
- SLIT2 | c.388T>A p.Y130N | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2
- SMARCC1 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2
- SMYD1 | c.53del p.G18Efs*4 | Frame Shift Del (DEL) | VAF 30/172 reads (17%) | called by mutect2, pindel, varscan2
- SNTN | c.286-1G>T p.X96_splice | Splice Site (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.466G>A p.V156M | Missense Mutation (SNP) | VAF 15/395 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.563); called by muse, mutect2
- SPHKAP | c.4613A>T p.Q1538L | Missense Mutation (SNP) | VAF 55/315 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SRSF3 | c.95A>G p.Y32C | Missense Mutation (SNP) | VAF 53/315 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- SSU72P8 | c.350A>G p.D117G | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ST3GAL4 | c.-60-5C>A | Splice Region (SNP) | VAF 14/205 reads (7%) | called by muse, mutect2
- STAG2 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SUPT20H | c.176G>A p.R59K (on ENST00000350612 / NM_001014286.3; = p.R60K on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- SUPT20HL2 | c.1788G>T p.Q596H | Missense Mutation (SNP) | VAF 74/286 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- SYNE3 | c.29A>G p.D10G | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SYT3 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.339); called by muse, mutect2
- SYTL5 | c.1272C>A p.Y424* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | called by mutect2, varscan2
- TAF1B | c.1716dup p.Y573Ifs*20 | Frame Shift Ins (INS) | VAF 12/74 reads (16%) | called by mutect2, pindel
- TARS1 | c.1160G>A p.G387D | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEK | c.2571G>A p.M857I | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- TENM3 | c.2535A>G p.I845M | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- TEX11 | c.566A>G p.E189G (on ENST00000344304; = p.E174G on NM_031276.3) | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX13C | c.2752C>A p.H918N | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.859); called by muse, mutect2
- TGFBR3 | c.2462T>A p.V821D | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- TGM2 | c.723G>T p.W241C | Missense Mutation (SNP) | VAF 69/355 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THSD7A | c.2933A>T p.K978I | Missense Mutation (SNP) | VAF 55/273 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- TICRR | c.1955C>T p.T652I | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TJP1 | c.2374C>G p.Q792E | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.741); called by muse, mutect2
- TMC2 | c.510G>T p.M170I | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM121B | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- TMEM132A | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 82/416 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TNKS1BP1 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TPK1 | c.186-1G>T p.X62_splice | Splice Site (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- TRABD | c.193A>C p.T65P | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- TRAPPC10 | c.831G>C p.K277N | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRHDE | c.2842A>T p.N948Y | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TRIM28 | c.448A>T p.N150Y | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TRIM31 | c.1088G>T p.R363L | Missense Mutation (SNP) | VAF 37/291 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TRIM49C | c.366del p.Y123Ifs*36 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | called by mutect2, varscan2
- TRIO | c.3017G>A p.R1006H | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRO | c.2166C>A p.N722K | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TSPYL4 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- TTC14 | c.1910C>T p.S637L | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2
- TTC37 | c.2246G>T p.G749V | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- TTC37 | c.2245G>T p.G749* | Nonsense Mutation (SNP) | VAF 20/118 reads (17%) | called by muse, mutect2, varscan2
- TTN | c.87574A>C p.T29192P (on ENST00000591111; = p.T21768P on NM_003319.4) | Missense Mutation (SNP) | VAF 23/208 reads (11%) | PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- TTN | c.71415T>A p.D23805E (on ENST00000591111; = p.D16381E on NM_003319.4) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TTN | c.64360C>G p.Q21454E (on ENST00000591111; = p.Q14030E on NM_003319.4) | Missense Mutation (SNP) | VAF 21/133 reads (16%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TXNRD2 | c.171G>T p.E57D | Missense Mutation (SNP) | VAF 22/377 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); called by muse, mutect2
- TYRP1 | c.75A>C p.Q25H | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- U2AF1L4 | c.638C>T p.P213L (on ENST00000412391; = p.L155= on NM_144987.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ULK1 | c.2049G>T p.E683D | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2
- UPF1 | c.3017C>T p.P1006L (on ENST00000599848 / NM_001297549.2; = p.P995L on NM_002911.4) | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2
- USP13 | c.1384A>G p.N462D | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); called by muse, mutect2
- USP31 | c.2398A>G p.S800G | Missense Mutation (SNP) | VAF 42/392 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- USP36 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- VCAN | c.3417A>T p.K1139N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- VPS13D | c.9418dup p.S3140Kfs*26 | Frame Shift Ins (INS) | VAF 29/149 reads (19%) | called by mutect2, pindel, varscan2
- WSCD2 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- WSCD2 | c.830G>A p.G277D | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); called by muse, mutect2
- YWHAH | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 21/332 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZAP70 | c.1040G>A p.G347D | Missense Mutation (SNP) | VAF 39/313 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB18 | c.140T>G p.M47R | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ZBTB18 | c.141G>T p.M47I | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- ZBTB38 | c.2800del p.M934* | Frame Shift Del (DEL) | VAF 29/247 reads (12%) | called by mutect2, pindel, varscan2
- ZC3H12B | c.2071C>A p.Q691K | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- ZDHHC21 | c.22G>C p.V8L | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- ZDHHC9 | c.891T>A p.D297E | Missense Mutation (SNP) | VAF 53/249 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- ZMYM6 | c.3323A>T p.E1108V | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- ZMYM6 | c.1451C>A p.T484N | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ZNF354A | c.121G>T p.D41Y | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- ZNF358 | c.1501G>T p.D501Y | Missense Mutation (SNP) | VAF 42/281 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ZNF431 | c.1213T>C p.C405R | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ZNF444 | c.868C>A p.R290S | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.103); called by muse, mutect2
- ZNF484 | c.2514G>A p.W838* | Nonsense Mutation (SNP) | VAF 15/81 reads (19%) | called by muse, mutect2
- ZNF485 | c.29C>A p.P10Q | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ZNF517 | c.454del p.R152Gfs*74 | Frame Shift Del (DEL) | VAF 12/116 reads (10%) | called by mutect2, pindel
- ZNF648 | c.863A>T p.Y288F | Missense Mutation (SNP) | VAF 73/302 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF681 | c.1654C>T p.H552Y | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF705A | c.10C>T p.L4= | Splice Region (SNP) | VAF 21/118 reads (18%) | called by muse, mutect2, varscan2
- ZNF750 | c.101G>A p.C34Y | Missense Mutation (SNP) | VAF 85/248 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF786 | c.1958G>A p.C653Y | Missense Mutation (SNP) | VAF 66/353 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF879 | c.892A>T p.K298* | Nonsense Mutation (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- ABCD1 | c.1671G>T p.V557= | Silent (SNP) | VAF 28/482 reads (6%) | called by muse, mutect2
- AC011462.1 | c.1026C>T p.N342= | Silent (SNP) | VAF 43/317 reads (14%) | catalogued as rs139390622; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACOT6 | c.171T>A p.I57= | Silent (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2, varscan2
- AKAP9 | c.10770C>T p.G3590= (on ENST00000359028; = p.G3566= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2
- ANK1 | c.4722G>A p.T1574= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs572098639, COSV55884518; called by muse, mutect2, varscan2
- ANKRD61 | c.402G>A p.T134= | Silent (SNP) | VAF 8/202 reads (4%) | catalogued as rs1277230504; called by muse, mutect2
- ANKS1A | c.540C>T p.N180= | Silent (SNP) | VAF 20/370 reads (5%) | called by muse, mutect2
- ARHGAP31 | c.3522C>T p.G1174= | Silent (SNP) | VAF 37/367 reads (10%) | called by muse, mutect2, varscan2
- ATG16L1 | c.540G>A p.L180= | Silent (SNP) | VAF 64/337 reads (19%) | catalogued as COSV61464282; called by muse, mutect2, varscan2
- ATP10A | c.1815G>T p.T605= | Silent (SNP) | VAF 61/466 reads (13%) | catalogued as COSV63514915; called by muse, mutect2, varscan2
- BCAP31 | c.204C>T p.R68= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as rs781786906, COSV61452613; called by muse, mutect2
- BCL11B | c.1152C>T p.R384= (on ENST00000357195 / NM_001282237.2; = p.R313= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs767442219; called by muse, mutect2, varscan2
- C16orf89 | c.1041T>C p.S347= | Silent (SNP) | VAF 19/78 reads (24%) | called by muse, mutect2, varscan2
- C4orf54 | c.3867C>T p.H1289= | Silent (SNP) | VAF 53/209 reads (25%) | catalogued as rs1264348036; called by muse, mutect2, varscan2
- CASK | c.1470G>T p.L490= | Silent (SNP) | VAF 32/129 reads (25%) | called by muse, mutect2, varscan2
- CBL | c.2073A>G p.Q691= | Silent (SNP) | VAF 41/225 reads (18%) | catalogued as rs140298671; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC22 | c.177T>A p.L59= | Silent (SNP) | VAF 69/251 reads (27%) | called by muse, mutect2, varscan2
- CDC42BPB | c.279C>G p.V93= | Silent (SNP) | VAF 18/115 reads (16%) | called by muse, mutect2, varscan2
- CEBPE | c.207C>A p.L69= | Silent (SNP) | VAF 39/245 reads (16%) | called by muse, mutect2, varscan2
- CEBPG | c.291C>G p.L97= | Silent (SNP) | VAF 28/244 reads (11%) | catalogued as COSV52287518; called by muse, varscan2
- CHD6 | c.378G>A p.E126= | Silent (SNP) | VAF 20/163 reads (12%) | called by muse, mutect2, varscan2
- CHRM2 | c.330A>G p.S110= | Silent (SNP) | VAF 33/405 reads (8%) | called by muse, mutect2
- CHRNB4 | c.1215G>T p.P405= | Silent (SNP) | VAF 50/290 reads (17%) | catalogued as rs765684498; called by muse, mutect2, varscan2
- CINP | c.570C>A p.P190= | Silent (SNP) | VAF 93/479 reads (19%) | catalogued as rs771320240; called by muse, mutect2, varscan2
- CLCN7 | c.1230C>T p.P410= | Silent (SNP) | VAF 143/713 reads (20%) | called by muse, mutect2, varscan2
- COL3A1 | c.186C>T p.C62= | Silent (SNP) | VAF 16/226 reads (7%) | catalogued as rs764749176, COSV58593556; ClinVar: likely benign; called by muse, mutect2
- COL6A6 | c.2007C>T p.I669= | Silent (SNP) | VAF 16/312 reads (5%) | called by muse, mutect2
- CSF3R | c.2397C>A p.T799= | Silent (SNP) | VAF 12/93 reads (13%) | called by muse, mutect2, varscan2
- CSMD3 | c.8538T>A p.G2846= (on ENST00000297405 / NM_001363185.1; = p.G2677= on NM_052900.3) | Silent (SNP) | VAF 30/157 reads (19%) | called by muse, mutect2, varscan2
- DGKB | c.1566T>A p.P522= | Silent (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- DHX16 | c.2685C>T p.S895= | Silent (SNP) | VAF 26/174 reads (15%) | called by muse, mutect2, varscan2
- DNTT | c.168C>A p.A56= | Silent (SNP) | VAF 37/162 reads (23%) | called by muse, mutect2, varscan2
- DRD2 | c.879C>T p.T293= | Silent (SNP) | VAF 27/146 reads (18%) | called by muse, mutect2, varscan2
- DTNB | c.1698C>T p.S566= | Silent (SNP) | VAF 39/379 reads (10%) | catalogued as rs557598647; called by muse, mutect2, varscan2
- DYTN | c.1626G>A p.T542= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs372227236, COSV101510826; called by mutect2, varscan2
- ELF3 | c.240G>T p.V80= | Silent (SNP) | VAF 13/326 reads (4%) | called by muse, mutect2
- ELK1 | c.726G>A p.R242= | Silent (SNP) | VAF 31/340 reads (9%) | called by muse, mutect2
- EPRS1 | c.1689T>C p.G563= | Silent (SNP) | VAF 20/148 reads (14%) | called by muse, mutect2, varscan2
- ERGIC3 | c.807G>A p.A269= | Silent (SNP) | VAF 30/197 reads (15%) | catalogued as rs376291998; called by muse, mutect2, varscan2
- ERMARD | c.393G>A p.S131= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as rs377727194; ClinVar: likely benign; called by muse, mutect2, varscan2
- EXOSC5 | c.453C>G p.L151= | Silent (SNP) | VAF 49/273 reads (18%) | called by muse, mutect2, varscan2
- F8 | c.5673A>G p.T1891= | Silent (SNP) | VAF 28/137 reads (20%) | called by muse, mutect2, varscan2
- FAM71E2 | c.684C>A p.A228= | Silent (SNP) | VAF 37/271 reads (14%) | catalogued as COSV99214912; called by muse, mutect2, varscan2
- FBXO42 | c.1380A>G p.V460= | Silent (SNP) | VAF 55/269 reads (20%) | called by muse, mutect2, varscan2
- FUS | c.669C>T p.G223= | Silent (SNP) | VAF 26/329 reads (8%) | catalogued as rs767226101, COSV54215211; ClinVar: likely benign; called by muse, mutect2
- GCOM1 | c.924C>T p.R308= | Silent (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2
- GLRB | c.663G>A p.V221= | Silent (SNP) | VAF 17/67 reads (25%) | called by muse, mutect2, varscan2
- GOLIM4 | c.57G>T p.L19= | Silent (SNP) | VAF 152/438 reads (35%) | catalogued as rs1338051823; called by muse, mutect2, varscan2
- GPR149 | c.792T>C p.S264= | Silent (SNP) | VAF 87/286 reads (30%) | catalogued as COSV67668225; called by muse, mutect2, varscan2
- HAPLN4 | c.1134C>A p.G378= | Silent (SNP) | VAF 39/161 reads (24%) | called by muse, mutect2, varscan2
- HECTD4 | c.10062C>T p.R3354= | Silent (SNP) | VAF 24/141 reads (17%) | catalogued as COSV101106532; called by muse, mutect2, varscan2
- HOMER3 | c.672C>T p.A224= | Silent (SNP) | VAF 24/187 reads (13%) | catalogued as rs1486468021; called by muse, mutect2, varscan2
- HPS6 | c.321C>T p.G107= | Silent (SNP) | VAF 41/165 reads (25%) | called by muse, mutect2, varscan2
- HRNR | c.2943C>A p.S981= | Silent (SNP) | VAF 147/664 reads (22%) | catalogued as rs142440614; called by muse, mutect2, varscan2
- HSPG2 | c.966G>A p.P322= | Silent (SNP) | VAF 20/271 reads (7%) | catalogued as rs374656693; called by muse, mutect2
- IFI6 | c.315C>T p.S105= | Silent (SNP) | VAF 25/176 reads (14%) | catalogued as rs780601796, COSV59269322; called by muse, mutect2, varscan2
- IGF2R | c.1161C>T p.S387= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as rs151169137; called by muse, mutect2, varscan2
- INPP5D | c.3234G>T p.V1078= (on ENST00000445964 / NM_001017915.3; = p.V1077= on NM_005541.5) | Silent (SNP) | VAF 34/220 reads (15%) | catalogued as rs764906056; called by muse, mutect2, varscan2
- IQCH | c.321T>C p.S107= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as rs1446537068; called by muse, mutect2, varscan2
- IRF2BP2 | c.387C>G p.L129= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as rs1183154966, COSV64015349; called by muse, mutect2
- ITGB4 | c.3198A>G p.E1066= | Silent (SNP) | VAF 140/381 reads (37%) | called by muse, mutect2, varscan2
- ITIH6 | c.3768A>G p.G1256= | Silent (SNP) | VAF 28/145 reads (19%) | called by muse, mutect2, varscan2
- JUND | c.75C>T p.F25= | Silent (SNP) | VAF 28/132 reads (21%) | called by muse, mutect2, varscan2
- KCNH4 | c.1851C>T p.D617= | Silent (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- KCNMB4 | c.522C>T p.F174= | Silent (SNP) | VAF 42/204 reads (21%) | catalogued as COSV50693204; called by muse, mutect2, varscan2
- KIAA1671 | c.4098G>A p.S1366= | Silent (SNP) | VAF 65/351 reads (19%) | catalogued as rs1235028064; called by muse, mutect2, varscan2
- KLF15 | c.42G>A p.S14= | Silent (SNP) | VAF 24/155 reads (15%) | catalogued as rs139765076; called by muse, mutect2, varscan2
- KLHDC7B | c.345C>G p.P115= (on ENST00000395676; = p.P756= on NM_138433.5) | Silent (SNP) | VAF 36/158 reads (23%) | called by muse, varscan2
- KLHL4 | c.138C>A p.T46= | Silent (SNP) | VAF 31/188 reads (16%) | catalogued as COSV64146581; called by muse, mutect2, varscan2
- KMT2D | c.10725G>A p.Q3575= | Silent (SNP) | VAF 26/125 reads (21%) | called by muse, mutect2, varscan2
- LAMC3 | c.597G>T p.P199= | Silent (SNP) | VAF 75/352 reads (21%) | catalogued as COSV63091042, COSV63093511; called by muse, mutect2, varscan2
- LIPC | c.666C>T p.T222= | Silent (SNP) | VAF 74/370 reads (20%) | called by muse, mutect2, varscan2
- LPAR4 | c.963C>T p.S321= | Silent (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- LRFN5 | c.504G>A p.E168= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV53250686; called by muse, mutect2, varscan2
- LRRC17 | c.498C>T p.H166= | Silent (SNP) | VAF 34/186 reads (18%) | called by muse, mutect2, varscan2
- LRRC4C | c.213G>A p.P71= | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as rs544953909; called by muse, varscan2
- LRRC70 | c.1428A>G p.L476= | Silent (SNP) | VAF 7/121 reads (6%) | called by muse, mutect2
- MDGA2 | c.1299T>C p.V433= (on ENST00000399232 / NM_001113498.2; = p.V135= on NM_182830.4) | Silent (SNP) | VAF 18/164 reads (11%) | called by muse, mutect2
- MED25 | c.924T>A p.P308= | Silent (SNP) | VAF 53/306 reads (17%) | catalogued as COSV57205873; called by muse, mutect2, varscan2
- MGRN1 | c.285G>A p.L95= | Silent (SNP) | VAF 76/359 reads (21%) | catalogued as rs376835705; called by muse, mutect2, varscan2
- MSANTD2 | c.1305C>T p.L435= (on ENST00000374979 / NM_001308027.2; = p.L383= on NM_024631.4) | Silent (SNP) | VAF 39/154 reads (25%) | catalogued as rs1268662121; called by muse, mutect2, varscan2
- MTMR6 | c.1353G>A p.K451= | Silent (SNP) | VAF 19/89 reads (21%) | called by muse, mutect2, varscan2
- MUC12 | c.15069C>T p.P5023= (on ENST00000379442; = p.P4880= on NM_001164462.1) | Silent (SNP) | VAF 32/199 reads (16%) | called by muse, mutect2, varscan2
- MUC17 | c.1980G>T p.V660= | Silent (SNP) | VAF 24/95 reads (25%) | called by muse, mutect2, varscan2
- MYH11 | c.1944C>T p.G648= | Silent (SNP) | VAF 38/499 reads (8%) | catalogued as rs1365590723; called by muse, mutect2
- MYO10 | c.3915G>A p.L1305= | Silent (SNP) | VAF 42/364 reads (12%) | called by muse, mutect2, varscan2
- MYO15B | c.3600C>T p.F1200= | Silent (SNP) | VAF 23/82 reads (28%) | called by muse, mutect2, varscan2
- MYO1E | c.654C>T p.G218= | Silent (SNP) | VAF 48/439 reads (11%) | catalogued as rs373337685; called by muse, mutect2, varscan2
- MYO7B | c.4204C>T p.L1402= | Silent (SNP) | VAF 79/452 reads (17%) | catalogued as COSV101268091; called by muse, mutect2, varscan2
- NFASC | c.465C>G p.G155= (on ENST00000339876 / NM_001378329.1; = p.G149= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/260 reads (11%) | called by muse, mutect2, varscan2
- NR4A3 | c.753G>A p.A251= | Silent (SNP) | VAF 22/251 reads (9%) | called by muse, mutect2
- OCA2 | c.2049G>T p.L683= | Silent (SNP) | VAF 28/174 reads (16%) | called by mutect2, varscan2
- OLFM3 | c.510C>T p.I170= (on ENST00000338858 / NM_001288821.1; = p.I150= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/186 reads (19%) | called by muse, mutect2, varscan2
- OR2J3 | c.339A>G p.T113= | Silent (SNP) | VAF 40/179 reads (22%) | called by muse, varscan2
- OR5M3 | c.783C>A p.P261= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100392611; called by muse, mutect2, varscan2
- OR8B12 | c.150G>A p.L50= | Silent (SNP) | VAF 37/170 reads (22%) | catalogued as rs775212633, COSV60910905; called by muse, mutect2, varscan2
- PAPOLG | c.2199C>T p.T733= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as rs1558726474; called by muse, mutect2, varscan2
- PDE1A | c.318G>T p.G106= | Silent (SNP) | VAF 16/133 reads (12%) | called by muse, mutect2, varscan2
- PDIA4 | c.1740C>T p.V580= (on ENST00000286091 / NM_001371244.1; = p.V579= on NM_004911.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/128 reads (24%) | called by muse, mutect2, varscan2
- PI15 | c.63C>T p.T21= | Silent (SNP) | VAF 38/223 reads (17%) | catalogued as rs146928869, COSV52642822; called by muse, mutect2, varscan2
- PIN4 | c.165T>C p.G55= (on ENST00000664196; = p.G30= on NM_006223.4) | Silent (SNP) | VAF 34/219 reads (16%) | called by muse, mutect2, varscan2
- PLEC | c.12276G>A p.K4092= (on ENST00000322810 / NM_201380.4; = p.K3982= on NM_000445.5) | Silent (SNP) | VAF 96/557 reads (17%) | catalogued as rs2857819; called by muse, mutect2, varscan2
- PLEKHG4 | c.1458C>T p.D486= | Silent (SNP) | VAF 22/278 reads (8%) | called by muse, mutect2
- PLXND1 | c.4344G>C p.L1448= | Silent (SNP) | VAF 83/304 reads (27%) | catalogued as rs143931927; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPP1R15B | c.471A>G p.K157= | Silent (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- PPP1R16B | c.156G>A p.E52= | Silent (SNP) | VAF 72/381 reads (19%) | catalogued as rs138967573; called by muse, mutect2, varscan2
- PRKCH | c.291C>T p.F97= | Silent (SNP) | VAF 27/174 reads (16%) | catalogued as rs561279740, COSV100273708, COSV60649962; called by muse, mutect2, varscan2
- PRLR | c.1788T>A p.T596= | Silent (SNP) | VAF 23/120 reads (19%) | called by muse, mutect2, varscan2
- PRR7 | c.510C>G p.L170= | Silent (SNP) | VAF 56/224 reads (25%) | called by muse, varscan2
- PTGDR | c.294C>T p.P98= | Silent (SNP) | VAF 51/297 reads (17%) | catalogued as rs769441347; called by muse, mutect2, varscan2
- PTPN5 | c.1380C>T p.P460= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as rs924121498; called by muse, mutect2, varscan2
- PTPRF | c.3339C>T p.D1113= | Silent (SNP) | VAF 20/181 reads (11%) | catalogued as rs148630488; called by muse, mutect2, varscan2
- PTPRN2 | c.336C>T p.L112= | Silent (SNP) | VAF 24/198 reads (12%) | catalogued as rs751005577; called by muse, mutect2, varscan2
- PURB | c.690G>A p.K230= | Silent (SNP) | VAF 28/454 reads (6%) | called by muse, mutect2
- RAPH1 | c.1986A>G p.P662= | Silent (SNP) | VAF 19/259 reads (7%) | catalogued as rs770975199; called by muse, mutect2
- RASSF3 | c.582C>T p.S194= | Silent (SNP) | VAF 26/121 reads (21%) | called by muse, mutect2, varscan2
- REXO1 | c.1779G>T p.A593= | Silent (SNP) | VAF 46/309 reads (15%) | catalogued as rs894626069; called by muse, mutect2, varscan2
- RPH3A | c.60C>A p.P20= | Silent (SNP) | VAF 20/97 reads (21%) | called by muse, mutect2, varscan2
- RPLP2 | c.138G>A p.L46= | Silent (SNP) | VAF 42/259 reads (16%) | catalogued as rs778708486; called by muse, mutect2, varscan2
- SAMD9L | c.423G>T p.V141= | Silent (SNP) | VAF 16/99 reads (16%) | called by muse, mutect2, varscan2
- SASH1 | c.357C>T p.S119= | Silent (SNP) | VAF 19/167 reads (11%) | catalogued as rs150780087; called by muse, mutect2, varscan2
- SCAF8 | c.3114G>T p.V1038= | Silent (SNP) | VAF 11/75 reads (15%) | called by muse, mutect2, varscan2
- SHPRH | c.4557G>C p.L1519= (on ENST00000275233 / NM_001042683.3; = p.L1523= on NM_173082.3) | Silent (SNP) | VAF 30/193 reads (16%) | catalogued as COSV51616949; called by muse, mutect2, varscan2
- SLC12A2 | c.1266T>C p.G422= | Silent (SNP) | VAF 15/62 reads (24%) | called by muse, mutect2, varscan2
- SLC9A3 | c.1137C>T p.S379= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as rs577512166, COSV99375772; called by muse, mutect2, varscan2
- SMPX | c.42C>T p.I14= | Silent (SNP) | VAF 49/259 reads (19%) | called by muse, mutect2, varscan2
- SNAP25 | c.387C>A p.I129= | Silent (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- SND1 | c.93C>T p.C31= | Silent (SNP) | VAF 19/144 reads (13%) | catalogued as rs372913206; called by muse, mutect2, varscan2
- SPARC | c.279C>T p.C93= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs760943159, COSV50557943; called by muse, mutect2, varscan2
- SPATA31D1 | c.4257T>C p.H1419= | Silent (SNP) | VAF 19/134 reads (14%) | called by muse, mutect2, varscan2
- SPEN | c.1959A>G p.R653= | Silent (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- SPICE1 | c.2262T>C p.L754= | Silent (SNP) | VAF 19/117 reads (16%) | called by muse, mutect2, varscan2
- SUV39H1 | c.90C>T p.C30= | Silent (SNP) | VAF 42/259 reads (16%) | catalogued as rs1557009029; called by muse, mutect2, varscan2
- SV2C | c.144G>T p.R48= | Silent (SNP) | VAF 27/120 reads (23%) | catalogued as COSV104399300; called by muse, mutect2, varscan2
- TAF8 | c.552C>T p.R184= | Silent (SNP) | VAF 52/342 reads (15%) | catalogued as rs374058625; called by muse, mutect2, varscan2
- TARBP1 | c.78G>A p.G26= | Silent (SNP) | VAF 36/414 reads (9%) | called by muse, mutect2
- TMEM8B | c.483C>T p.C161= | Silent (SNP) | VAF 43/209 reads (21%) | called by muse, mutect2, varscan2
- TMPRSS9 | c.78T>C p.C26= | Silent (SNP) | VAF 40/257 reads (16%) | called by muse, mutect2, varscan2
- TMTC2 | c.1785A>G p.L595= | Silent (SNP) | VAF 54/254 reads (21%) | called by muse, varscan2
- TNC | c.210A>T p.S70= | Silent (SNP) | VAF 85/452 reads (19%) | called by muse, mutect2, varscan2
- TNRC18 | c.4959G>C p.G1653= | Silent (SNP) | VAF 40/346 reads (12%) | called by muse, mutect2, varscan2
- TONSL | c.360C>A p.I120= | Silent (SNP) | VAF 24/353 reads (7%) | called by muse, mutect2
- TRAPPC12 | c.1200C>T p.C400= | Silent (SNP) | VAF 24/393 reads (6%) | catalogued as rs1417140672; called by muse, mutect2
- TRBV2 | c.15C>A p.L5= | Silent (SNP) | VAF 31/196 reads (16%) | called by muse, mutect2, varscan2
- TRIM51GP | c.255C>T p.F85= | Silent (SNP) | VAF 45/220 reads (20%) | called by muse, mutect2, varscan2
- TSC2 | c.2493G>A p.T831= | Silent (SNP) | VAF 28/410 reads (7%) | catalogued as rs773645613, COSV54772276; called by muse, mutect2
- TTLL2 | c.177C>G p.G59= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as rs947214424; called by muse, mutect2, varscan2
- UBA1 | c.1710C>T p.G570= | Silent (SNP) | VAF 21/325 reads (6%) | catalogued as rs1556790843; ClinVar: uncertain significance; called by muse, mutect2
- UPP1 | c.681C>T p.Y227= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as rs1200301114; called by muse, mutect2
- USP44 | c.609A>G p.A203= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as rs955031405; called by muse, mutect2, varscan2
- UTRN | c.3102C>T p.G1034= | Silent (SNP) | VAF 26/154 reads (17%) | called by muse, mutect2, varscan2
104 further variants in this file (0 protein-altering or splice-affecting, 13 silent, 91 other) are not listed here.
